TCGA case TCGA-HD-7229 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5c48e21f-1fe9-4007-9b0c-7ca766586fff

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 60.4 years (22,076 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: NX; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cetuximab + Paclitaxel; Days to treatment start: 35 days; Days to treatment end: 85 days.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 35 days; Days to treatment end: 85 days; Treatment dose: 7,000 cGy; Number of fractions: 35; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Docetaxel + Fluorouracil; Days to treatment start: 187 days; Days to treatment end: 187 days; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Cure; Days to treatment end: 85 days.
2. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Larynx, NOS. Age at diagnosis: 60.9 years (22,238 days); Days to diagnosis: 162 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.

Follow-up (4 entries)
- Days to follow up: 2 days; Disease response: With Tumor.
- Day 162 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Larynx, NOS; Days to recurrence: 162 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Days to follow up: 316 days; Disease response: With Tumor.
- Days to follow up: 1,027 days (2.8 years); Disease response: With Tumor.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HD-7229-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.3; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-HD-7229-01A-01-TS1: Section location: Top; Percent tumor cells: 87; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 8; Percent stromal cells: 5.
- Sample TCGA-HD-7229-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HD-7229-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Tobacco smoking history indicator: 3; Alcohol history documented: No.
- Drug treatment 3: Pharmaceutical therapy drug name: Erbitux.
- Drug treatment 4: Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Pharmaceutical therapy drug name: 5-FU; Treatment best response: Clinical Progressive Disease.
- Follow-up form 1: Lost to follow-up: No; Tumor status: With tumor; Tobacco smokeless use at diagnosis: No.
- Follow-up form 2: Lost to follow-up: No; Tumor status: With tumor; Definitive treatment method: Radiation.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous malignancy of the thyroid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,027 days; disease-specific survival: no event (censored), 1,027 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 162 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HD-7229-01A-11D-2010-01): tumor purity 0.57, ploidy 2.17, whole-genome doublings 0.
